Surgical pathology report (de-identified scan), TCGA case TCGA-24-1562, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1562-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Other Related Clinical Data:

DIAGNOSIS: OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA
- CYSTADENOFIBROMA

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA
- PARAOVARIAN ADHESIONS WITH METASTATIC ADENOCARCINOMA

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA INVOLVING PARATUBAL SOFT TISSUE

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA INVOLVING PARATUBAL SOFT TISSUE

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- INACTIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- LEIOMYOMA

OMENTUM, OMENTECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

BLADDER, FLAP, BIOPSY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

[page 2 of 4]
[REDACTED]

CUL-DE-SAC, TUMOR, BIOPSY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

UMBILICUS, NODULE, EXCISION
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

[REDACTED] By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By [REDACTED] **

Microscopic Description and Comment: Papillary serous adenocarcinoma is present in the right and left ovaries. In the left ovary, the tumor predominantly involves paraovarian adhesions. In the right ovary, benign serous cystadenofibroma is present adjacent to invasive papillary serous carcinoma. Extensive metastatic papillary serous adenocarcinoma is present in right and left paratubal soft tissues, the omentum and in the specimens labeled "bladder flap," "cul-de-sac tumor," and "umbilical nodule."

History: The patient is a [REDACTED] with a right ovarian mass on ultrasound and an elevated CA125. Operative procedure: Exploratory laparotomy, omentectomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy and optimal tumor debulking.

Specimen(s) Received:

A: OMENTUM
B: BLADDER FLAP
C: CUL DE SAC TUMOR
D: HYSTERECTOMY, BSO
E: UMBILICAL NODULE

Gross Description The specimens are received in five containers of formalin, each labeled with the patient's name. The first container is additionally labeled "omentum." It consists of a 40 x 15 x 5 cm omental cake extensively involved by a solid, tan-yellow tumor mass. Labeled A1 - A3. [REDACTED]

The second container is labeled "bladder flap." It consists of irregular grey-tan, tumor-like tissue measuring 3.5 x 2.5 x 2 cm in aggregate. [REDACTED]

The third container is labeled "cul-de-sac tumor." It consists of a 2.5 x 1 x 0.8 cm grey-tan nodule, compatible with tumor. [REDACTED]

The fourth container is labeled "uterus, cervix, BSO." It consists of a 92 gram, 7.5 x 4 x 3 cm uterus with attached bilateral adnexae. The serosa of the uterus, except for the presence of a subserosal leiomyoma, is smooth and unremarkable. The ectocervix measures 3.5 cm in greatest diameter and is covered by a grey-tan, slightly hemorrhagic mucosa. The endocervix is 2.5 cm in length and has a slightly mucoid, yellow, mucosa that is free of tumor. The endometrial cavity measures 2.5 x 1.5 cm and has an unremarkable tan-yellow mucosa. The myometrium is composed of a coarsely trabeculated musculature, that, except for the presence of a circumscribed, white, whorled, 7 mm leiomyoma is grossly unremarkable. The right ovary has previously been opened. It measures approximately 3 x 2 x 2 cm and is apparently largely replaced by a unilocular cyst. The cyst contains a single solid tan-yellow papillary area measuring 1.0 cm in greatest dimension and covering less than 10% of the total cyst surface area. The remaining surface area is smooth, glistening and unremarkable. The right fallopian tube measures 4.5 cm in length and has fimbria at the distal end. There are three small tumor nodules in the paratubal soft tissues that measure

[page 3 of 4]
[REDACTED]

up to 8 mm in greatest dimension. The tube, appears grossly free of tumor. The left adnexal structures are ill-defined grossly, due to the presence of numerous hemorrhagic adhesions. There appears to be a portion of ovary that measures 2 x 1 x 0.4 cm. There are nodular excrescences on the surface but these appear to represent hemorrhagic exudate. Sectioning of the ovary shows a normal-appearing grey-white stroma, without gross evidence of tumor. There is also a distorted portion of fallopian tube that has fimbria distally and appears grossly uninvolved by tumor. Labeled D1, anterior cervix; D2, anterior endomyometrium; D3, posterior cervix; D4, posterior endomyometrium; D5, subserosal leiomyoma; D6 - D12, completely embedded right adnexal tissue; D13 - D20 completely embedded left adnexal tissues. [REDACTED]

The fifth container is labeled "umbilical nodule." It consists of an irregular 3 x 3 x 2 cm fragment of fibrosis tissue. The sectioned tissue shows specimen replacement of the adipose tissue by tumor. [REDACTED]

[REDACTED]

Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. PRESENT

A neoplasm is

2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Right and left ovary (synchronous primary tumors)
5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES invade the adjacent paratubal soft tissue.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is: >2.0 cm.
14. Metastatic involvement of the uterine serosa is ABSENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is: 0
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
	T3c	IIIC

[page 4 of 4]
Macroscopic peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension,
OR Regional lymph node metastasis OR Metastasis to capsule of liver.

THE REGIONAL LYMPH NODES are classified as: NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO

X Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after
integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 87d5f12c-ae8b-432e-97b5-10406367da18 (TCGA-24-1562.0CE36DAF-9512-4860-A5A3-B2FF7F487C5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).